Somatic mutation profile of tumor specimen TCGA-LI-A9QH-01A (aliquot TCGA-LI-A9QH-01A-11D-A37C-09) from TCGA case TCGA-LI-A9QH, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 72.5 years (26,468 days).
Specimen TCGA-LI-A9QH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2c82438-713f-4039-9df6-42c4aaf5bc46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LI-A9QH-10A (Blood Derived Normal), aliquot TCGA-LI-A9QH-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a18fe35c-1a03-4346-83a1-a54957e3b61f

The open-access MAF lists 90 somatic variants for this specimen: 64 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 22, Nonsense Mutation 4, Splice Site 3, 3'UTR 2, Frame Shift Ins 1, Frame Shift Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 92/93 reads (99%) | hotspot (GDC flag); catalogued as rs1567555445, CS951538, COSV52663569, COSV52668477, COSV52702628; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ACO1 | c.266+1G>A p.X89_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | catalogued as rs1200741849, COSV59379534, COSV59381007; called by muse, mutect2, varscan2
- AMY2B | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs750106406, COSV63716287, COSV63717305; called by muse, mutect2, varscan2
- ATM | c.4766C>T p.S1589L | Missense Mutation (SNP) | VAF 74/93 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV99587018; called by muse, mutect2, varscan2
- C1QTNF5 | c.541T>A p.F181I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as COSV100264688; called by muse, mutect2, varscan2
- CCNA1 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV99714246; called by muse, mutect2, varscan2
- CELSR3 | c.6436G>A p.V2146I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs199670636; called by muse, mutect2, varscan2
- COL4A1 | c.1630G>T p.G544* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV101010943; called by muse, mutect2, varscan2
- CTNNA3 | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146777494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYBB | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as rs781992322, COSV101059723, COSV66085391, COSV66085499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAOA | c.74T>A p.F25Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV100298668; called by muse, mutect2, varscan2
- DOCK6 | c.2350G>A p.V784M | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs753109339, COSV99370842; called by muse, mutect2, varscan2
- FAXC | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.568); catalogued as rs1448440317, COSV67604171; called by muse, mutect2, varscan2
- FBXO36 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.987); catalogued as rs1057372884, COSV99391381; called by muse, mutect2, varscan2
- FER1L6 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs369182988; called by muse, mutect2, varscan2
- GPT2 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.758); catalogued as rs1045338829, COSV60840389; called by muse, mutect2, varscan2
- H6PD | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs763065812, COSV101072410; called by muse, mutect2, varscan2
- HIPK3 | c.3010G>A p.G1004S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.015); catalogued as COSV100305322; called by muse, mutect2
- IL2RB | c.587A>G p.E196G | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99344617; called by muse, mutect2, varscan2
- IRS4 | c.2172T>G p.N724K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV100929397; called by muse, mutect2, varscan2
- ITGA4 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs749317117, COSV99275667; called by muse, mutect2, varscan2
- KCNT1 | c.845T>C p.L282P (on ENST00000488444; = p.L301P on NM_020822.3) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV99704852; called by muse, mutect2, varscan2
- KIF21B | c.3551G>A p.R1184Q | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.36); PolyPhen benign (0.111); catalogued as rs371053876; called by muse, mutect2, varscan2
- KIF26A | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs370868498; called by muse, mutect2, varscan2
- KLHL1 | c.1192C>G p.L398V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100916926; called by muse, mutect2, varscan2
- LINS1 | c.1161A>T p.L387F | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100129925; called by muse, mutect2, varscan2
- LRCH2 | c.2216G>C p.R739P | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100406177, COSV57748926; called by muse, mutect2, varscan2
- LRRC30 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs922460592, COSV101274366; called by muse, mutect2
- MAG | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs142036180; called by muse, mutect2, varscan2
- MAP3K7 | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.536); catalogued as COSV100997848; called by muse, mutect2
- MECOM | c.2309T>A p.F770Y (on ENST00000468789 / NM_001105078.4; = p.F958Y on NM_004991.4) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99243913; called by muse, mutect2, varscan2
- MED12L | c.3957G>T p.E1319D | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99851329; called by muse, mutect2
- MUC16 | c.7072C>T p.R2358W | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs372186047, COSV67485774; called by muse, mutect2, varscan2
- MYH11 | c.1988A>G p.K663R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.052); catalogued as COSV100257559; called by muse, mutect2, varscan2
- MYO15A | c.3043G>T p.E1015* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as COSV99230918; called by muse, mutect2, varscan2
- MYOCD | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV100590073; called by muse, mutect2, varscan2
- NPTXR | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs780696214, COSV100285326; called by muse, mutect2, varscan2
- OR11G2 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs1368541419, COSV100639897, COSV100639919; called by muse, mutect2, varscan2
- OR51I2 | c.679G>C p.A227P | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV100413276; called by muse, mutect2, varscan2
- P2RY12 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs947116652, COSV99851328; called by muse, varscan2
- PFKFB4 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | PolyPhen probably damaging (1); catalogued as rs943355847, COSV99219287; called by muse, mutect2, varscan2
- PPP1R35 | c.494T>C p.V165A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV99439752; called by muse, mutect2, varscan2
- RAD23A | c.750G>C p.Q250H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100330385; called by muse, mutect2, varscan2
- RALGPS2 | c.1718A>G p.Q573R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.109); catalogued as COSV100860600; called by muse, mutect2, varscan2
- RAP1A | c.140A>C p.D47A | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV100712674; called by muse, mutect2, varscan2
- RHCG | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748212663, COSV51518301; called by muse, mutect2, varscan2
- SHANK1 | c.6221G>A p.R2074H | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs759453731, COSV99520083; called by muse, mutect2, varscan2
- SPAG7 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV99236141; called by muse, mutect2
- TCERG1L | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100893780; called by muse, mutect2, varscan2
- TEX11 | c.1529-1G>C p.X510_splice (on ENST00000344304; = p.X495_splice on NM_031276.3) | Splice Site (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100721281; called by muse, mutect2, varscan2
- TMEM244 | c.241T>G p.F81V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV100933517; called by muse, mutect2
- TMEM87A | c.419A>T p.D140V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV100213141; called by muse, mutect2, varscan2
- TNIK | c.2098G>C p.G700R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV99454743; called by muse, mutect2, varscan2
- TOM1L1 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.169); catalogued as COSV100779122; called by muse, mutect2, varscan2
- TRPC3 | c.979G>C p.E327Q (on ENST00000379645 / NM_001366479.2; = p.E254Q on NM_003305.2) | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99312032; called by muse, mutect2
- TTC23L | c.955G>C p.V319L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs535984245, COSV101533375; called by muse, varscan2
- TTN | c.79489A>C p.S26497R (on ENST00000591111; = p.S19073R on NM_003319.4) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | PolyPhen probably damaging (0.997); catalogued as COSV100592183; called by muse, mutect2, varscan2
- TXNRD1 | c.1348A>T p.I450F (on ENST00000525566 / NM_001093771.3; = p.I352F on NM_003330.4) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV100723263; called by muse, mutect2, varscan2
- UBQLN2 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100592613; called by muse, mutect2, varscan2
- UGT1A6 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs751579554, COSV59394170; called by muse, mutect2, varscan2
- ZNF366 | c.646A>T p.K216* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100574044; called by muse, mutect2, varscan2
- DRICH1 | c.55A>G p.K19E | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.801); called by muse, mutect2
- FAM133B | c.271dup p.R91Kfs*13 | Frame Shift Ins (INS) | VAF 16/59 reads (27%) | called by mutect2, varscan2
- PPP1R3A | c.2295del p.I766Sfs*3 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, varscan2
- ACLY | c.2340G>A p.K780= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100709496; called by muse, mutect2
- ACTRT3 | c.613A>C p.R205= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV100377322; called by muse, mutect2, varscan2
- ADAMTS20 | c.543G>A p.K181= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs758632950, COSV101238787; called by muse, mutect2, varscan2
- ASH1L | c.5022A>G p.P1674= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100853078; called by muse, mutect2, varscan2
- BEST4 | c.954C>T p.D318= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs369088764; called by muse, mutect2, varscan2
- CACNA1B | c.3426C>T p.F1142= | Silent (SNP) | VAF 43/43 reads (100%) | catalogued as COSV99494947; called by muse, mutect2, varscan2
- CEP170B | c.2508C>T p.G836= (on ENST00000453495; = p.G765= on NM_015005.3) | Silent (SNP) | VAF 50/50 reads (100%) | catalogued as rs771925178, COSV69025346; called by muse, mutect2, varscan2
- FBN3 | c.2151C>T p.A717= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV54468289; called by muse, mutect2, varscan2
- GPT | c.342G>A p.A114= | Silent (SNP) | VAF 87/124 reads (70%) | catalogued as rs756909307, COSV52952235, COSV52952313, COSV99477330; called by muse, mutect2, varscan2
- KIF19 | c.387C>T p.N129= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs747262363, COSV100738912; called by muse, mutect2, varscan2
- MAD1L1 | c.1824G>A p.V608= | Silent (SNP) | VAF 24/30 reads (80%) | catalogued as COSV99765004; called by muse, mutect2
- MYO16 | c.5388G>T p.V1796= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV100695396; called by muse, mutect2, varscan2
- MYO18B | c.460T>C p.L154= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100122454; called by muse, mutect2, varscan2
- NLRP2 | c.1434C>T p.S478= | Silent (SNP) | VAF 18/21 reads (86%) | catalogued as rs771520385, COSV54753768; called by muse, mutect2, varscan2
- NWD1 | c.4008C>T p.I1336= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs376902807; called by muse, mutect2, varscan2
- OR2M5 | c.21C>T p.T7= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs751103552, COSV100822725, COSV63546873; called by muse, mutect2, varscan2
- PCDHA12 | c.2034G>A p.T678= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV56494590; called by muse, mutect2, varscan2
- SEMG2 | c.774T>C p.D258= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV101033937; called by muse, mutect2
- TAAR6 | c.903T>C p.Y301= | Silent (SNP) | VAF 48/84 reads (57%) | catalogued as COSV99256441; called by muse, mutect2, varscan2
- TUBA3D | c.1125G>A p.V375= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100342252; called by muse, mutect2, varscan2
- ZNF274 | c.936C>T p.Y312= (on ENST00000610905; = p.Y207= on NM_016324.3) | Silent (SNP) | VAF 19/23 reads (83%) | catalogued as COSV100464656; called by muse, mutect2, varscan2
- ZNF565 | c.222G>A p.V74= (on ENST00000355114; = p.V34= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as COSV100411727; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851244 C>A | 3'Flank (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- GP6 | c.*335A>G | 3'UTR (SNP) | VAF 8/14 reads (57%) | catalogued as COSV100117371; called by muse, mutect2, varscan2
- OSCAR | c.*457A>C | 3'UTR (SNP) | VAF 27/87 reads (31%) | catalogued as COSV99499809; called by muse, mutect2, varscan2
- SSPOP | n.3157C>G | RNA (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100022101; called by muse, mutect2, varscan2
